Somatic mutation profile of tumor specimen 52d61ab1-5781-4b47-8e88-37c2ea (aliquot 52d61ab1-5781-4b47-8e88-37c2ea_D6) from CPTAC case 11CO020, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 52d61ab1-5781-4b47-8e88-37c2ea: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7c98e4e-5793-40c6-b266-c878c92c37bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0318bcea-2ea7-471a-9f42-5f5ccd (Blood Derived Normal), aliquot 0318bcea-2ea7-471a-9f42-5f5ccd_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e479da3-f905-40a2-a0ba-87844051a9a6

The open-access MAF lists 180 somatic variants for this specimen: 112 protein-altering or splice-affecting, 44 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 44, Intron 13, Splice Site 4, Nonsense Mutation 4, 5'UTR 4, Frame Shift Ins 3, 5'Flank 3, RNA 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 234/432 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 75/438 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1218013224, COSV55116336; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1406+1G>A p.X469_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as rs138068719; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 267/585 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs1223643234; called by muse, mutect2, varscan2
- ADCK5 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 327/563 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58233397, COSV58233509; called by muse, mutect2, varscan2
- ARFGEF3 | c.577G>T p.G193W | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.619); catalogued as rs767802448; called by muse, mutect2, varscan2
- ATM | c.3682G>T p.E1228* | Nonsense Mutation (SNP) | VAF 56/251 reads (22%) | catalogued as COSV53734573; called by muse, mutect2, varscan2
- ATP6V0A1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99230318; called by muse, mutect2, varscan2
- ATP8A2 | c.2956+2T>C p.X986_splice | Splice Site (SNP) | VAF 54/156 reads (35%) | catalogued as rs774105637, COSV99682834; called by muse, mutect2, varscan2
- C1QL1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1052317799; called by muse, mutect2, varscan2
- CCDC144A | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747697017, COSV61403097; called by mutect2, varscan2
- CCSER1 | c.2698G>T p.G900W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100389413; called by muse, mutect2, varscan2
- CEP162 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs143441616; called by muse, mutect2, varscan2
- CHAT | c.1262G>T p.W421L | Missense Mutation (SNP) | VAF 189/556 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119378; called by muse, mutect2, varscan2
- COQ4 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs929713295; called by muse, mutect2, varscan2
- CXorf58 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs372943491; called by mutect2, varscan2
- DNAH5 | c.4613C>T p.A1538V | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201165908, COSV99444675, COSV99448650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYS | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 132/767 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs755588849; called by muse, mutect2, varscan2
- EDNRA | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 129/306 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.416); catalogued as rs146147419; called by muse, mutect2, varscan2
- FAM50A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs782158952; called by muse, mutect2, varscan2
- FOXD4L6 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 102/794 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1215164463; called by mutect2, varscan2
- GALNT13 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 151/251 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777690153, COSV67216575; called by muse, mutect2, varscan2
- GDPD2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 117/152 reads (77%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs145392379, COSV65533805; called by muse, mutect2, varscan2
- GPR4 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs551669816, COSV100547203; called by muse, mutect2, varscan2
- HEATR5B | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs140557608; called by muse, mutect2, varscan2
- HID1 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762065351; called by muse, mutect2, varscan2
- ITPRIP | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs145318706, COSV53392980; called by muse, mutect2, varscan2
- LRFN1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429071595, COSV99953062; called by muse, mutect2, varscan2
- MANBA | c.1942C>A p.H648N (on ENST00000642252; = p.H602N on NM_005908.4) | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV56965795, COSV99898456; called by muse, mutect2
- MROH5 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 205/370 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs199532269; called by muse, mutect2, varscan2
- MSH4 | c.1010G>A p.G337D | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1359575088; called by muse, mutect2, varscan2
- MTUS2 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs767698168; called by muse, mutect2, varscan2
- NCAM2 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV53085220; called by muse, mutect2, varscan2
- NID1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 184/501 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.238); catalogued as rs765323590, COSV51615303; called by muse, mutect2, varscan2
- NOS3 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs776830535; called by muse, mutect2
- PALLD | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs775675053; called by muse, mutect2, varscan2
- PCDH9 | c.1463T>A p.L488* | Nonsense Mutation (SNP) | VAF 129/364 reads (35%) | catalogued as COSV60565800; called by muse, mutect2, varscan2
- PLEKHG4B | c.1919C>T p.T640M (on ENST00000283426; = p.T996M on NM_052909.5) | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs542561152; called by muse, mutect2, varscan2
- PREX2 | c.1493G>T p.R498I | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55759339; called by muse, mutect2, varscan2
- PTCHD3 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 310/482 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs779458816; called by muse, mutect2, varscan2
- PTPRD | c.3669A>C p.Q1223H | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.188); catalogued as COSV61950936; called by muse, mutect2
- RYR1 | c.14773G>A p.V4925I | Missense Mutation (SNP) | VAF 270/726 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs959737076, COSV100614796; called by mutect2, varscan2
- RYR3 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66799807; called by muse, mutect2, varscan2
- SCOC | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV58393196, COSV58394076; called by muse, mutect2, varscan2
- SIPA1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868747260; called by muse, mutect2, varscan2
- SLC52A3 | c.1265G>C p.R422P | Missense Mutation (SNP) | VAF 113/216 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200665228, COSV54077951; called by muse, varscan2
- SNX20 | c.496G>C p.G166R | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs778514926; called by muse, mutect2, varscan2
- TAS2R41 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1312322229, COSV68764959; called by muse, mutect2
- TENM2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV101595353; called by muse, mutect2, varscan2
- TENT5D | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100382511; called by muse, mutect2, varscan2
- TMEM25 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs200390061, COSV57097704; called by muse, mutect2, varscan2
- UBXN6 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147364683; called by muse, mutect2, varscan2
- USF3 | c.3637C>A p.P1213T | Missense Mutation (SNP) | VAF 30/514 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs771933399; called by muse, mutect2
- VCAN | c.5040C>G p.S1680R | Missense Mutation (SNP) | VAF 269/607 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as rs746936031; called by muse, mutect2, varscan2
- VGLL3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1335449303, COSV67352631; called by muse, mutect2, varscan2
- VPS52 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs754737136, COSV71403397; called by muse, mutect2, varscan2
- ZCCHC13 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 196/277 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100272496, COSV59866426; called by muse, mutect2, varscan2
- ZDBF2 | c.2679G>T p.K893N | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV65630887; called by muse, mutect2, varscan2
- ZFHX4 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as rs1050373982, COSV51473220; called by mutect2, varscan2
- ZNF181 | c.526dup p.I176Nfs*4 | Frame Shift Ins (INS) | VAF 36/304 reads (12%) | catalogued as rs777165974; called by mutect2, pindel, varscan2
- ZPLD1 | c.628C>T p.P210S (on ENST00000466937 / NM_001329788.1; = p.P226S on NM_175056.2) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs372677453; called by muse, mutect2, varscan2
- ACAD11 | c.963+2T>C p.X321_splice | Splice Site (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- ADGRV1 | c.10489C>A p.Q3497K | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ALG8 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APC | c.4338_4339insAC p.Q1447Tfs*27 | Frame Shift Ins (INS) | VAF 62/272 reads (23%) | called by mutect2, varscan2
- ATM | c.7677_7702dup p.R2568Ifs*5 | Frame Shift Ins (INS) | VAF 70/285 reads (25%) | called by mutect2, varscan2
- BNIP3L | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTN1A1 | c.1196A>T p.Y399F | Missense Mutation (SNP) | VAF 84/690 reads (12%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- C6orf58 | c.688T>C p.S230P | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CACNA2D3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CAPN13 | c.884A>T p.E295V | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CDC40 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CNOT1 | c.2669G>A p.C890Y | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN1 | c.1505C>A p.T502K | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- DCLK1 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- DCST2 | c.107T>C p.L36S | Missense Mutation (SNP) | VAF 228/540 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- FBXO24 | c.1721G>T p.G574V (on ENST00000241071 / NM_033506.3; = p.G612V on NM_012172.5) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, mutect2
- FGF12 | c.434G>T p.C145F (on ENST00000454309 / NM_021032.5; = p.C83F on NM_004113.6) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNTL5 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ICE1 | c.4167G>C p.E1389D | Missense Mutation (SNP) | VAF 25/584 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- IFIT1B | c.1110G>C p.K370N | Missense Mutation (SNP) | VAF 136/230 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IGFBP6 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCP | c.4436G>A p.C1479Y (on ENST00000620378; = p.C1603Y on NM_001366122.1) | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP4-2 | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 104/588 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); called by mutect2, varscan2
- MCM3 | c.1967T>C p.V656A (on ENST00000229854 / NM_001366374.2; = p.V646A on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/285 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MPDZ | c.3709T>C p.F1237L | Missense Mutation (SNP) | VAF 91/414 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL45 | c.161A>T p.K54M | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- MYO3B | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK3 | c.2091C>A p.D697E | Missense Mutation (SNP) | VAF 191/776 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OAS3 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OR2L8 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 176/486 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PCDHAC2 | c.1481C>G p.T494R | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PLEKHH1 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2
- PRSS16 | c.1180T>C p.F394L | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRSS33 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- RGPD3 | c.3517G>C p.D1173H | Missense Mutation (SNP) | VAF 142/676 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGPD4 | c.3662A>G p.N1221S | Missense Mutation (SNP) | VAF 76/460 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO4 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEC63 | c.1198A>T p.N400Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SKIV2L | c.3488G>A p.G1163E | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC37A2 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 108/384 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC9C2 | c.2144G>T p.R715M | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCC1 | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN4 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT6H | c.345+2T>A p.X115_splice | Splice Site (SNP) | VAF 51/251 reads (20%) | called by muse, mutect2, varscan2
- TRPC4 | c.978G>A p.W326* | Nonsense Mutation (SNP) | VAF 172/398 reads (43%) | called by muse, mutect2, varscan2
- VEPH1 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 132/368 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- VSTM2L | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB49 | c.1495A>T p.K499* | Nonsense Mutation (SNP) | VAF 64/188 reads (34%) | called by muse, mutect2, varscan2
- ZNF408 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 94/568 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, varscan2
- ZNF549 | c.431G>C p.G144A (on ENST00000376233 / NM_001199295.2; = p.G131A on NM_153263.2) | Missense Mutation (SNP) | VAF 74/442 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF844 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACSM6 | c.1380C>T p.D460= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs1440139930, COSV58981221; called by muse, mutect2, varscan2
- AHNAK | c.10758C>A p.I3586= | Silent (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2, varscan2
- AKAP9 | c.2748C>G p.V916= | Silent (SNP) | VAF 75/169 reads (44%) | catalogued as COSV100661915; called by muse, mutect2, varscan2
- ARFGEF1 | c.3675G>T p.G1225= | Silent (SNP) | VAF 104/167 reads (62%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.1500A>C p.A500= | Silent (SNP) | VAF 36/594 reads (6%) | called by muse, mutect2
- ATP10D | c.2787C>T p.N929= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- BNIP5 | c.1743C>A p.T581= | Silent (SNP) | VAF 88/555 reads (16%) | called by muse, mutect2, varscan2
- CACNG8 | c.891G>A p.P297= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- CC2D1A | c.2388C>G p.A796= | Silent (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2
- CNTNAP1 | c.672G>A p.T224= | Silent (SNP) | VAF 196/501 reads (39%) | catalogued as rs754704710; called by muse, mutect2, varscan2
- COBLL1 | c.843T>C p.F281= (on ENST00000392717; = p.F243= on NM_014900.5) | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- CRACDL | c.900G>A p.P300= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CRYBG3 | c.1221G>A p.T407= | Silent (SNP) | VAF 82/242 reads (34%) | catalogued as rs1277119582; called by muse, mutect2, varscan2
- CRYGB | c.21C>T p.Y7= | Silent (SNP) | VAF 369/594 reads (62%) | catalogued as rs758440322, COSV53680421; called by muse, mutect2, varscan2
- DCBLD2 | c.798A>G p.E266= | Silent (SNP) | VAF 92/375 reads (25%) | called by muse, mutect2, varscan2
- DOCK4 | c.2181C>T p.N727= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs190956823; called by muse, mutect2, varscan2
- FBXL19 | c.1317G>A p.R439= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- FNBP4 | c.1470A>G p.E490= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- GMPS | c.609G>A p.L203= | Silent (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- GRIA2 | c.2436C>T p.N812= | Silent (SNP) | VAF 72/159 reads (45%) | catalogued as rs570651579; called by muse, mutect2, varscan2
- HMX3 | c.459T>C p.S153= | Silent (SNP) | VAF 68/118 reads (58%) | called by muse, mutect2, varscan2
- KIF1A | c.3675C>T p.S1225= | Silent (SNP) | VAF 304/417 reads (73%) | catalogued as rs775591104, COSV57493072; ClinVar: likely benign; called by muse, varscan2
- LOXHD1 | c.4860C>T p.Y1620= | Silent (SNP) | VAF 135/237 reads (57%) | catalogued as rs982841436; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAPT | c.1947G>A p.K649= (on ENST00000262410 / NM_001377265.1; = p.K257= on NM_005910.5) | Silent (SNP) | VAF 87/400 reads (22%) | called by muse, mutect2, varscan2
- MON1A | c.990G>A p.A330= | Silent (SNP) | VAF 102/241 reads (42%) | catalogued as COSV56559420; called by muse, mutect2, varscan2
- MYOM2 | c.2544C>T p.F848= | Silent (SNP) | VAF 73/190 reads (38%) | catalogued as rs558634230, COSV50732142; called by muse, mutect2, varscan2
- NLRP14 | c.2709G>A p.T903= | Silent (SNP) | VAF 234/665 reads (35%) | catalogued as rs200194625, COSV55065882, COSV55072804; called by muse, mutect2, varscan2
- NUTM2G | c.930G>A p.P310= | Silent (SNP) | VAF 108/387 reads (28%) | catalogued as rs752245352; called by muse, mutect2, varscan2
- OPCML | c.258T>A p.P86= | Silent (SNP) | VAF 26/446 reads (6%) | catalogued as rs757480737; called by muse, mutect2
- P4HTM | c.1488C>T p.R496= (on ENST00000383729 / NM_177939.3; = p.R557= on NM_177938.2) | Silent (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2
- PATL1 | c.2227C>T p.L743= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV55689448; called by muse, mutect2, varscan2
- PCDHGA6 | c.108C>T p.P36= | Silent (SNP) | VAF 144/291 reads (49%) | catalogued as rs780279453; called by muse, mutect2, varscan2
- PPARGC1B | c.273C>T p.A91= | Silent (SNP) | VAF 53/241 reads (22%) | called by muse, mutect2, varscan2
- PRDM13 | c.837G>A p.S279= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- PRSS1 | c.363C>T p.A121= | Silent (SNP) | VAF 73/693 reads (11%) | catalogued as COSV61194235; called by muse, mutect2, varscan2
- RASAL3 | c.2262G>A p.P754= | Silent (SNP) | VAF 50/221 reads (23%) | catalogued as rs370506475, COSV99653210; called by muse, mutect2, varscan2
- RIPOR3 | c.2634G>A p.A878= | Silent (SNP) | VAF 177/401 reads (44%) | catalogued as rs763204438, COSV50396667; called by muse, mutect2, varscan2
- RPN1 | c.1452C>T p.T484= | Silent (SNP) | VAF 99/636 reads (16%) | called by muse, mutect2, varscan2
- SALL3 | c.1614C>T p.H538= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as rs773279214, COSV73305996; called by muse, mutect2, varscan2
- SLC9A9 | c.1570C>A p.R524= | Silent (SNP) | VAF 40/215 reads (19%) | catalogued as COSV57248096; called by muse, mutect2, varscan2
- SPATC1 | c.1311G>A p.S437= | Silent (SNP) | VAF 58/286 reads (20%) | catalogued as rs782000209; called by muse, mutect2, varscan2
- USP42 | c.972C>T p.T324= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs151011297, COSV60358938; called by muse, mutect2, varscan2
- ZNF335 | c.1278C>T p.S426= | Silent (SNP) | VAF 70/298 reads (23%) | catalogued as COSV59817845; called by muse, mutect2, varscan2
- ZNF454 | c.927T>C p.F309= | Silent (SNP) | VAF 127/309 reads (41%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501543 G>A | 5'Flank (SNP) | VAF 32/210 reads (15%) | catalogued as rs1271541994; called by muse, mutect2, varscan2
- CDK14 | c.124-16972C>T | Intron (SNP) | VAF 25/126 reads (20%) | catalogued as rs751679131, COSV56057844; called by muse, mutect2, varscan2
- CTSA | c.-22G>A | 5'UTR (SNP) | VAF 10/116 reads (9%) | catalogued as rs1335691231; called by muse, mutect2
- EIF2A | c.476-3dup | Intron (INS) | VAF 53/166 reads (32%) | catalogued as rs769244111; called by mutect2, varscan2
- EYS | c.1767-8247C>A | Intron (SNP) | VAF 12/76 reads (16%) | called by mutect2, varscan2
- FBXL19 | c.*589G>A | 3'UTR (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- FOXR2 | c.-1G>T | 5'UTR (SNP) | VAF 44/67 reads (66%) | catalogued as COSV100189377; called by muse, mutect2, varscan2
- IGFN1 | c.1241+1963G>A | Intron (SNP) | VAF 128/369 reads (35%) | called by muse, mutect2, varscan2
- LAG3 | c.59-20C>G | Intron (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- LAG3 | c.59-19C>T | Intron (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- LINC00583 | n.56T>C | RNA (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- LNPK | c.707-1340G>T | Intron (SNP) | VAF 86/139 reads (62%) | called by muse, mutect2, varscan2
- MACF1 | c.220+18313G>C | Intron (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- MIR6859-3 | chr15:101975092 C>T | 3'Flank (SNP) | VAF 66/560 reads (12%) | called by muse, mutect2, varscan2
- NFATC4 | chr14:24367191 G>T | 5'Flank (SNP) | VAF 56/372 reads (15%) | catalogued as COSV99144490; called by muse, mutect2, varscan2
- PPP1R2P1 | n.427C>T | RNA (SNP) | VAF 80/514 reads (16%) | catalogued as rs750123594; called by muse, mutect2, varscan2
- SLC2A14 | c.88-6954A>T | Intron (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- TOP1MT | c.-7A>G | 5'UTR (SNP) | VAF 60/228 reads (26%) | called by muse, varscan2
- TPK1 | c.185+1080A>G | Intron (SNP) | VAF 32/142 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.34265-4477C>T | Intron (SNP) | VAF 220/314 reads (70%) | catalogued as rs769994195; called by muse, mutect2, varscan2
- Y_RNA | chr12:54102314 T>A | 5'Flank (SNP) | VAF 192/497 reads (39%) | called by muse, mutect2, varscan2
- ZNF114 | c.-18G>A | 5'UTR (SNP) | VAF 78/408 reads (19%) | catalogued as rs965173265, COSV100251964; called by muse, mutect2, varscan2
- ZNF254 | c.158-33G>A | Intron (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- ZNF454 | c.-108+36G>A | Intron (SNP) | VAF 41/279 reads (15%) | called by muse, mutect2, varscan2
